Surgical pathology report (de-identified scan), TCGA case TCGA-HT-A61C, project TCGA-LGG (Brain Lower Grade Glioma), tissue source site Case Western - St Joes, specimen TCGA-HT-A61C-01A (Primary Tumor).

Pathology Report for

Discussion:

Numerous MIB-1 reactive cells are present throughout the tumor. A labeling index of 34.7 percent is calculated. A minority of the cells are positive for p53. The tumor is negative for IDH1.

Diagnosis:

Left temporal anaplastic oligodendroglioma, grade III.

- MIB-1 LI = 34.7%

Microscopic Description:

Sections demonstrate a markedly hypercellular diffusely infiltrating glial neoplasm. The tumor cells consistently have perinuclear halos. Nuclei are round to oval to oblong and moderately atypical. Numerous scattered mitotic figures are seen. There is focally prominent microvascular laceration as well as occasional foci of confluent tumor necrosis. Definite cystic differentiation is not seen.

Dual/Synchronous Primary Site(s)		
Case is (Clinical):		
Reviewer: ML Date Review: 3/29/13		

Source: NCI Genomic Data Commons file 30868b13-b5ea-4da6-b874-196cebcfe9ba (TCGA-HT-A61C.D3039C78-0727-4215-8EE9-DBADCA775531.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).